Gene-level copy-number profile of tumor specimen HTMCP-03-06-02354-01C from CGCI case HTMCP-03-06-02354, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 51.9 years (18,947 days).
Specimen HTMCP-03-06-02354-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6efb527b-f32b-4ca0-bde2-83726a9c3389.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02354-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/1e7f4c05-fc18-42b6-a1e5-a50cc9c0b4a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 878; copy number 2: 21,419; copy number 3: 13,977; copy number 4: 17,787; copy number 5: 2,675; copy number 6: 1,511; copy number 7: 18; copy number 8: 12; copy number 15: 2; copy number 16: 12; copy number 17: 2; copy number 20: 18; copy number 26: 2; copy number 31: 30; copy number 33: 8.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,928,253, 11 genes (within-gene range 0–2): PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–4): RNU6-904P, RPS16P3.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–2): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:75,521,803–75,542,929, 2 genes (within-gene range 0–2): SNRPCP10, RPS3AP15.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr21:46,635,595–46,691,226, 3 genes: PRMT2, DSTNP1, RPL23AP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,290 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,708,148, 75 genes, copy number 6 (broad region; genes not listed).
- chr1:152,106,317–152,196,699, 4 genes, copy number 6 (within-gene range 4–6): TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:167,430,640–167,518,610, 2 genes, copy number 5 (within-gene range 4–5): CD247, AL359962.3.
- chr1:167,519,536–168,376,876, 23 genes, copy number 5: AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557.
- chr1:168,401,483–168,451,211, 2 genes, copy number 5: AL022100.2, QRSL1P1.
- chr1:246,682,108–246,691,821, 2 genes, copy number 7: AL591848.2, AL591848.1.
- chr3:196,739,857–196,832,647, 1 gene, copy number 6 (within-gene range 4–6): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 6: RNU6-42P.
- chr5:58,198–45,895,970, 679 genes, copy number 6–7 (broad region; genes not listed).
- chr5:151,652,275–151,686,975, 2 genes, copy number 5 (within-gene range 2–5): AC011374.1, SPARC.
- chr6:105,919–27,865,798, 526 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:27,911,185–31,765,588, 304 genes, copy number 5 (broad region; genes not listed).
- chr6:35,443,044–66,094,909, 500 genes, copy number 5–6 (broad region; genes not listed).
- chr7:142,482,548–142,802,748, 50 genes, copy number 5: TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr8:36,004,316–43,674,591, 186 genes, copy number 6–33 (broad region; genes not listed).
- chr9:60,914,407–62,813,486, 50 genes, copy number 5: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283.
- chr9:127,579,370–138,253,217, 401 genes, copy number 5 (broad region; genes not listed).
- chr12:1,500,525–1,504,424, 1 gene, copy number 5: LINC00942.
- chr12:2,695,765–4,118,132, 42 genes, copy number 6 (within-gene range 4–6): ITFG2-AS1, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1.
- chr13:44,432,143–48,976,867, 93 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:73,399,031–73,408,352, 2 genes, copy number 7: AL162376.1, MARK2P12.
- chr13:100,062,296–100,063,601, 1 gene, copy number 7: ASNSP3.
- chr14:18,333,726–19,653,742, 59 genes, copy number 5–7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8.
- chr14:21,997,539–22,501,663, 67 genes, copy number 6 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr14:59,135,488–59,371,405, 3 genes, copy number 5: AKR1B1P5, PPIAP5, DAAM1.
- chr14:59,479,274–79,868,291, 457 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr14:79,639,754–79,644,431, 1 gene, copy number 5: AC008056.3.
- chr15:19,878,555–20,291,586, 22 genes, copy number 5: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2.
- chr17:21,376,357–21,641,536, 14 genes, copy number 6–8: KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1.
- chr17:57,971,547–75,941,140, 513 genes, copy number 5–15 (broad region; genes not listed).
- chr17:79,074,824–83,106,910, 189 genes, copy number 5 (broad region; genes not listed).
- chr19:14,514,769–14,572,066, 4 genes, copy number 5: DNAJB1, TECR, MIR639, NDUFB7.
- chr19:43,192,702–43,269,530, 3 genes, copy number 5: PSG4, CEACAMP10, PSG9.
- chr21:8,759,077–9,059,060, 10 genes, copy number 5: LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4.

Autosomal genes at a single copy (total copy number 1): 878. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
